Gene-level copy-number profile of tumor specimen TCGA-02-0052-01A from TCGA case TCGA-02-0052, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.4 years (18,061 days).
Specimen TCGA-02-0052-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.06c4368a-7d16-41b2-8441-bce041995995.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-02-0052-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ff5cf55-df2f-4556-a289-c7e9ff8510cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,067; copy number 2: 50,662; copy number 3: 3,075; copy number 40: 9; copy number 42: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0052-01): tumor purity 0.52, ploidy 3.9, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:68,332,888–68,451,663, 1 gene, copy number 42 (within-gene range 2–42): LINC02384.
- chr12:68,426,331–68,487,863, 3 genes, copy number 42: AC008033.3, AC008033.1, AC008033.2.
- chr12:68,686,951–68,971,570, 9 genes, copy number 40 (within-gene range 2–40): NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM.

Autosomal genes at a single copy (total copy number 1): 3,685. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
